Somatic mutation profile of tumor specimen TCGA-HC-7230-01A (aliquot TCGA-HC-7230-01A-11D-2114-08) from TCGA case TCGA-HC-7230, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 50.9 years (18,577 days).
Specimen TCGA-HC-7230-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be1c073b-aaa0-4c5b-8d72-d407c35c3f03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7230-10A (Blood Derived Normal), aliquot TCGA-HC-7230-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e620b95-9679-4548-a6c3-ed7d93cdf45b

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, Splice Region 2, RNA 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 20/122 reads (16%) | hotspot (GDC flag); catalogued as rs1554898097, COSV64289174; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 32/57 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKIB1 | c.2063A>G p.E688G | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56062939; called by muse, mutect2, varscan2
- CAPNS1 | c.488A>C p.E163A | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55823010; called by muse, mutect2, varscan2
- DCP2 | c.976T>C p.Y326H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV66617321; called by muse, mutect2, varscan2
- FPR2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.378); catalogued as rs1181203136, COSV60673235; called by muse, mutect2, varscan2
- KRT6A | c.1477G>A p.V493I | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs201432146, COSV58105498; called by muse, mutect2, varscan2
- MMP16 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54158218, COSV54171273; called by muse, mutect2
- NTNG1 | c.1392G>A p.P464= (on ENST00000370068 / NM_001113226.3; = p.T363= on NM_014917.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 11/49 reads (22%) | catalogued as rs1263780229, COSV64270814; called by muse, mutect2, varscan2
- OR5L2 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 41/386 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs1447484429, COSV65724371; called by muse, mutect2, varscan2
- PHKA1 | c.2078T>A p.V693E | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV59807311; called by muse, mutect2
- RAG1 | c.2626G>A p.E876K | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs145772007, COSV55025933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELA | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV58015100; called by muse, mutect2, varscan2
- ROR1 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as rs749580497, COSV64285967; called by muse, mutect2, varscan2
- SCN3B | c.219+1G>A p.X73_splice | Splice Site (SNP) | VAF 56/163 reads (34%) | catalogued as COSV54799816; called by muse, mutect2, varscan2
- TLR7 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101028075, COSV66124604; called by muse, mutect2, varscan2
- TNPO1 | c.2340A>G p.A780= | Splice Region (SNP) | VAF 46/129 reads (36%) | catalogued as COSV61522311; called by muse, mutect2, varscan2
- TRIM42 | c.1378A>G p.T460A | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV53884133; called by muse, mutect2
- CYYR1 | c.354C>T p.H118= | Silent (SNP) | VAF 55/133 reads (41%) | catalogued as rs576432831, COSV54829051; called by muse, mutect2, varscan2
- EFHD1 | c.594C>T p.A198= | Silent (SNP) | VAF 95/247 reads (38%) | catalogued as COSV51133028; called by muse, mutect2, varscan2
- POLR1G | c.741G>A p.P247= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as rs749731534, COSV50004471; called by muse, mutect2, varscan2
- PROSER1 | c.2193C>T p.T731= | Silent (SNP) | VAF 14/237 reads (6%) | catalogued as rs750557799, COSV61485999; called by muse, mutect2
- RASGEF1C | c.63C>T p.T21= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as rs748536339, COSV63181583; called by muse, mutect2
- SLC37A1 | c.745A>C p.R249= | Silent (SNP) | VAF 31/176 reads (18%) | catalogued as COSV61402917; called by muse, mutect2, varscan2
- ZFYVE1 | c.1086G>A p.T362= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as rs762699227, COSV59611594; called by muse, mutect2, varscan2
- AC073310.1 | n.187C>G | RNA (SNP) | VAF 43/101 reads (43%) | catalogued as rs765230363; called by muse, mutect2, varscan2
